Gene-level copy-number profile of tumor specimen TCGA-UY-A78P-01A from TCGA case TCGA-UY-A78P, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Transitional cell carcinoma; Tissue or organ of origin: Bladder, NOS; AJCC pathologic stage: Stage II; Tumor grade: High Grade; Age at diagnosis: 78.6 years (28,719 days).
Specimen TCGA-UY-A78P-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-BLCA.d26e6987-4fb7-4653-9650-1951bb2dc8aa.absolute_liftover.gene_level_copy_number.v36.tsv, workflow ABSOLUTE segment calls lifted over to GRCh38 (Affymetrix SNP 6.0); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 4,342 have no estimate.
https://portal.gdc.cancer.gov/files/77b75630-3da9-428e-9456-bdab199c4b67

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 382; copy number 1: 7,725; copy number 2: 45,108; copy number 3: 2,127; copy number 4: 642; copy number 5: 209; copy number 6: 16; copy number 7: 72.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-UY-A78P-01A-12D-A363-01): tumor purity 0.26, ploidy 1.98, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 382 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:20,999,509–22,128,103, 53 genes (within-gene range 0–3): HACD4, IFNNP1, IFNB1, IFNWP4, AL390882.1, IFNW1, Y_RNA, IFNA21, IFNWP15, IFNA4, IFNWP9, IFNA7, IFNA10, IFNWP18, IFNA16, IFNA17, IFNWP5, IFNA14, IFNA22P, IFNA5, IFNA20P, KLHL9, IFNA6, IFNA13, IFNA2, AL353732.1, IFNA11P, IFNA12P, IFNA8, AL353732.2, IFNWP2, IFNA1, MIR31HG, IFNWP19, IFNE, MIR31, SNORD39, H3P30, KHSRPP1, RN7SL151P, MTAP, AL359922.1, TUBB8P1, AL359922.2, AL359922.3, ERVFRD-3, CDKN2A-DT, CDKN2A, CDKN2B-AS1, AL449423.1, CDKN2B, UBA52P6, AL354709.1.
- chr12:12,049,844–12,357,067, 11 genes: BCL2L14, PTMAP9, MIR1244-4, LRP6, AC007537.1, RNU6-545P, AC007621.3, RNU6-318P, MANSC1, RPL23AP66, LOH12CR2.
- chr19:281,040–6,020,363, 312 genes (broad region; genes not listed).
- chr21:20,651,450–21,686,329, 6 genes (within-gene range 0–1): LINC00320, PPIAP1, NCAM2, AP001136.1, AP001117.1, AF241725.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 297 genes in 7 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:169,572,328–170,482,195, 18 genes, copy number 5: AC084724.1, CLCN3, HPF1, PTGES3P3, AC079768.1, AC079768.3, AC079768.4, LINC02275, AC079768.2, AC084866.2, AC084866.1, MFAP3L, AADAT, APOBEC3AP1, AC069306.1, LINC01612, LINC02512, AC074255.1.
- chr4:171,113,789–171,638,763, 7 genes, copy number 5–6 (within-gene range 1–6): AC034159.1, AC092639.1, MIR6082, LINC02504, AC074254.2, LINC02174, AC074254.1.
- chr5:50,396,192–60,522,120, 153 genes, copy number 5–7 (within-gene range 1–7) (broad region; genes not listed).
- chr12:9,448,295–11,590,369, 97 genes, copy number 5 (within-gene range 1–5) (broad region; genes not listed).
- chr12:27,958,084–28,581,511, 10 genes, copy number 5: PTHLH, AC008011.2, CCDC91, AC022364.1, AC022364.2, AC022079.2, AC022079.1, RNU4-54P, RNA5SP355, AC084754.1.
- chr19:42,752,686–42,855,691, 1 gene, copy number 6 (within-gene range 2–6): PSG8.
- chr19:42,821,863–43,171,515, 11 genes, copy number 6 (within-gene range 2–6): PSG8-AS1, PSG10P, PSG1, PSG6, PSG7, CEACAMP7, AC004784.1, PSG11, CEACAMP8, PSG2, CEACAMP9.

Autosomal genes at a single copy (total copy number 1): 7,725. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
